CCDI case PBCGJV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/8549f0d2-9518-4014-a457-e37f1925db7c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 2.2 years (809 days).

Biospecimens (3 samples)
- Sample 0DRY7Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRY7W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRY86: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
